Gene-level copy-number profile of tumor specimen TCGA-IN-A7NU-01A from TCGA case TCGA-IN-A7NU, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 69.9 years (25,515 days).
Specimen TCGA-IN-A7NU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.63173448-88f9-4a94-9e57-299208d88307.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IN-A7NU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3c00cdc2-5469-43a7-be95-cf6de2b2b1a9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 366; copy number 2: 13,449; copy number 3: 16,225; copy number 4: 24,835; copy number 5: 2,939; copy number 6: 317; copy number 7: 952; copy number 8: 381; copy number 9: 28; copy number 10: 79; copy number 11: 22; copy number 12: 40; copy number 13: 29; copy number 14: 14; copy number 15: 9; copy number 18: 15; copy number 19: 32; copy number 23: 8; copy number 25: 11; copy number 48: 12; copy number 49: 25; copy number 52: 23; copy number 81: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IN-A7NU-01A-22D-A34T-01): tumor purity 0.53, ploidy 1.75, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,732,636, 5 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 350 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:62,118,300–63,827,445, 18 genes, copy number 9: RNU2-10P, ID2B, PTPRG-AS1, C3orf14, FEZF2, CADPS, AC012519.1, RN7SL863P, RNU6-139P, AC096915.1, LINC00698, KRT8P35, UBL5P3, SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1.
- chr6:50,514,035–50,913,256, 7 genes, copy number 13: AL360175.1, AL135908.1, TFAP2D, TFAP2B, RPS17P5, AL049693.1, FTH1P5.
- chr6:106,695,535–109,094,819, 56 genes, copy number 12–25 (within-gene range 2–25): LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12, SOBP, AL121957.1, AL096816.1, SCML4, SEC63, RNU6-437P, RPL23AP50, AL024507.2, AL024507.1, SNORA73, MTHFD2P3, RPL3P7, Z98200.1, OSTM1, Y_RNA, OSTM1-AS1, NR2E1, AL078596.1, SNX3, Z98742.2, RNA5SP212, Z98742.4, Z98742.1, RNU6-1144P, AFG1L, Z98742.3, AL356121.2, AL356121.1, AL353706.1, RNU6-770P, AL139106.1, AL391646.1, FOXO3, SUMO2P8, LINC00222, ZNF259P1, Z95118.2, Z95118.1, ARMC2, AL445189.1, ATP5MFP2, ARMC2-AS1, SESN1, AL390208.1, RNU6-653P.
- chr10:71,396,920–72,355,149, 19 genes, copy number 10 (within-gene range 4–10): CDH23, CDH23-AS1, C10orf105, VSIR, MIR7152, PSAP, RNU7-38P, AC073370.1, CHST3, AC022392.1, SPOCK2, ASCC1, AL607035.1, RPL15P14, ANAPC16, Y_RNA, DDIT4, DDIT4-AS1, DNAJB12.
- chr10:72,391,964–72,392,069, 1 gene, copy number 10: RNU6-805P.
- chr12:1,529,891–1,647,212, 1 gene, copy number 48 (within-gene range 2–48): WNT5B.
- chr12:1,660,315–2,004,535, 11 genes, copy number 48 (within-gene range 2–48): MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B.
- chr12:22,008,348–24,562,544, 21 genes, copy number 52 (within-gene range 2–81): AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1, SOX5.
- chr12:24,212,421–25,648,579, 30 genes, copy number 49–81: MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1.
- chr18:11,326,270–11,670,165, 14 genes, copy number 12: AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1, SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, MIR7153, AP001120.1.
- chr18:23,004,564–27,247,188, 78 genes, copy number 10–18 (broad region; genes not listed).
- chr18:27,343,252–27,401,910, 3 genes, copy number 10: AC021382.1, UBA52P9, AC068408.1.
- chr18:35,241,030–36,780,055, 35 genes, copy number 9–23 (within-gene range 2–23): ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24, ZNF396, AC007998.1, AC007998.4, AC007998.3, AC007998.2, INO80C, AC007998.5, GALNT1, MIR3975, AC090220.1, AC090229.1, NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A, SLC39A6, ELP2, AC023043.1, MOCOS, AC023043.4, AC023043.2, AC023043.3, FHOD3, AC055840.1.
- chr18:48,539,031–48,863,217, 1 gene, copy number 14 (within-gene range 7–14): CTIF.
- chr18:48,661,840–49,461,347, 13 genes, copy number 14 (within-gene range 2–14): AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3, AC016866.1, DYM, MIR4744, AC016866.2, AC044840.1.
- chr18:64,872,264–66,069,647, 9 genes, copy number 15 (within-gene range 2–15): AC090348.1, AC007948.1, AC007631.1, LINC01916, AC090358.1, CDH7, AC023394.2, AC023394.1, PRPF19P1.
- chr18:74,597,870–76,260,114, 28 genes, copy number 10 (within-gene range 2–10): ZNF407, AC015819.2, AC015819.1, AC015819.4, AC015819.3, AC015819.5, ZADH2, TSHZ1, AC116003.3, AC116003.1, SMIM21, AC116003.2, AC012101.2, AC012101.1, AC090812.1, AC090338.1, LINC01898, AC021506.1, AC021506.2, AC090457.1, AC011095.1, AC103808.6, LINC01893, AC103808.2, AC103808.4, AC103808.3, AC103808.1, AC103808.5.
- chr20:56,667,430–56,786,087, 5 genes, copy number 9: RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P.

Autosomal genes at a single copy (total copy number 1): 366. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
